Surgical pathology report (de-identified scan), TCGA case TCGA-43-6770, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-43-6770-01A (Primary Tumor).

[page 1 of 2]
DEPARTMENT OF PATHOLOGY AND LABORATORY MEDICINE

SURGICAL PATHOLOGY REPORT

SPECIMEN

- A. Left upper lobe
- B. Level 10 lymph node
- C. Level 5 lymph node
- D. Level 7 lymph node

CLINICAL NOTES

PRE-OP DIAGNOSIS: Chest mass.

GROSS DESCRIPTION

A. Received fresh, subsequently fixed in formalin labeled "left upper lobe" is a 196 gram, 16 x 11 x 4.5 cm. lobe of lung which is partially covered with a gray violaceous smooth glistening pleura which shows diffuse black stippling. The hilum is heavily stapled. There is a 1.5 cm. umbilication which is located opposite of the hilum. This area is inked blue and the specimen is sectioned in this area to show a 3.2 x 3.2 x 2.3 cm. well-circumscribed white-tan indurated lesion. This comes within 4.5 cm. of the hilar margin. This is contiguous with the umbilication. The remainder of the parenchyma is red-pink and spongy showing no other discrete gross lesions identified. Possible hilar node is grossly identified. Representative sections of the specimen are submitted as follows:

BLOCK SUMMARY: 1 - bronchial and vascular margins; 2 - possible hilar node; 3 - representative normal; 4-8 - representative section of tumor which includes normal parenchyma and tumor to umbilication. RS-8.

B. Received fresh, subsequently fixed in formalin labeled "level 10 lymph node" is a 1.5 x 1.0 x 0.4 cm aggregate of pink-red irregular soft tissue fragments which are grossly consistent with possible lymphoid tissue. The specimens are entirely submitted in one cassette. AS-1.

C. Received fresh, subsequently fixed in formalin labeled "level 5 lymph node" are multiple pink-gray irregular soft friable tissue fragment which have an aggregate measurement of 3.5 x 2.5 x 0.5 cm. The specimens are entirely submitted in two cassettes. AS-2.

D. Received fresh subsequently fixed in formalin labeled "level 7 lymph node" are multiple pink, gray irregular soft tissue fragments which have aggregate measurement of 2.0 x 2.0 x 0.4 cm. The specimens are entirely submitted in one cassette. AS-1.

MICROSCOPIC DESCRIPTION

Histologic type: Squamous cell carcinoma.

Histologic grade: Poorly differentiated with extensive areas of necrosis.

Primary tumor (pT): pT2a, the tumor measures 3.2 cm. in dimension

[page 2 of 2]
[REDACTED]

and extends up to the visceral pleura and very focal visceral pleural invasion cannot be excluded.
Margins of resection: Negative.
Direct extension of tumor: The tumor is limited to the lung.
Vascular invasion: Present.
Regional lymph nodes (pN): pN0.
Distant metastasis (pM): pMx.

5x1 and 3x3

DIAGNOSIS

- A. Lung, left upper lobe, excision - Poorly differentiated squamous cell carcinoma (see tumor characteristics in the microscopic description).
Five hilar lymph nodes negative for metastatic carcinoma (0/5).
- B. Lymph nodes, level 10, excision - Two lymph nodes negative for metastatic carcinoma (0/2).
- C. Lymph nodes, level 5, excision - Multiple fragments of lymph node negative for metastatic carcinoma.
- D. Lymph node, level 7, excision - Three lymph nodes negative for metastatic carcinoma (0/3).
- [REDACTED]
- [REDACTED]
- [REDACTED]
- [REDACTED]

--- End Of Report ---

Source: NCI Genomic Data Commons file 7666bf1e-158d-4645-a2b4-fc849bcddca3 (TCGA-43-6770.CACFD9DD-AAD5-48D8-9ECC-3DB108BFF2F8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).